TCGA case TCGA-C5-A1M6 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/825a6fbb-aede-436f-800b-c7f096da0a77

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Dead; Days to death: 955 days (2.6 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,090 days); Year of diagnosis: 1998; Method of diagnosis: Biopsy; FIGO stage: Stage IIB; FIGO staging edition year: 1995; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, Combination; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Days to treatment end: 75 days; Treatment dose: 4,500 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin; Days to treatment start: 341 days; Days to treatment end: 489 days (1.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 341 days; Days to treatment end: 489 days (1.3 years); Number of cycles: 6; Prescribed dose: 10; Prescribed dose units: mg/m2/day; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mitomycin + Vincristine; Days to treatment start: 341 days; Days to treatment end: 489 days (1.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Therapeutic Hydrocortisone; Days to treatment start: 341 days; Days to treatment end: 489 days (1.3 years); Treatment outcome: Progressive Disease.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 55.9 years (20,406 days); Days to diagnosis: 316 days; Prior treatment: Yes.

Follow-up (8 entries)
- Day 204 (post adjuvant therapy): ECOG performance status: 0.
- Day 316 (preoperative): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 316 days; Days to imaging: 316 days; Imaging type: CT Scan; Imaging result: Negative; Evidence of progression type: Convincing Image Source; Imaging findings: Bladder Involvement.
- Day 316 (preoperative): Days to imaging: 316 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 316 (preoperative): Days to imaging: 316 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 316 (preoperative): Days to imaging: 316 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 316 (preoperative): Days to imaging: 316 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 316 (preoperative): Days to imaging: 316 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Days to follow up: 955 days (2.6 years); Disease response: With Tumor.

Molecular and laboratory tests
- Human Papillomavirus: Positive [Hpv strain: HPV18].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77 kg; Height: 165 cm; BMI: 28.3.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A1M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-C5-A1M6-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 2.
- Sample TCGA-C5-A1M6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A1M6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 1; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 1; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other).
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Present; Ct scan preop results: Parametrium Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Human papillomavirus types: HPV types positive: HPV 18.
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Performance status timing: Post-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Radiation adjuvant indicator: Yes; Brachytherapy status: Completed as planned; Radiation therapy xrt type: External beam radiation; New tumor event type: Distant Metastasis; New tumor event site: Lung; New tumor event surgery: CT; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, Radiation supplemental: Radiation treatment total dose to pelvis: 5840; Radiation therapy status: Completed as Planned; Chemo concurrent reason not given: Not done per treating physicians discretion.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Cisplatinum; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Pharmaceutical therapy drug name: Mitomycin C; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Pharmaceutical therapy drug name: Hydrocortisone; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 955 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 955 days; disease-free interval: event (new tumor event after initially disease-free), 316 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 316 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A1M6-01A-11D-A13V-01): tumor purity 0.73, ploidy 2.69, whole-genome doublings 1.
